RC case RC-B65H — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/329f99a7-c08a-49e6-8bba-7c2aac915b58

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1946; Vital status: Dead; Days to death: 992 days (2.7 years); Year of death: 2016.

Diagnoses (1)
1. T-cell large granular lymphocytic leukemia: ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,718 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Bone marrow / Spleen / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Initial Diagnosis; Days to treatment start: 6 days; Days to treatment end: 6 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin + Methotrexate; Initial disease status: Initial Diagnosis; Regimen or line of therapy: HD-MTX-LCV; Days to treatment start: 6 days; Days to treatment end: 6 days; Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 71 days; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Stopped Due to Toxicity; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 144 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 992.

Molecular and laboratory tests
- Epstein-Barr Virus: Negative [Test analyte type: DNA].
- Lactate Dehydrogenase 355 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Turner's Syndrome.
- Timepoint category: Initial Diagnosis; Weight: 37.4 kg; Height: 133 cm; BMI: 21.1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample RC-B65H-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65H-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
